Somatic mutation profile of tumor specimen TCGA-DD-AACA-02B (aliquot TCGA-DD-AACA-02B-11D-A40R-10) from TCGA case TCGA-DD-AACA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 65.6 years (23,973 days).
Specimen TCGA-DD-AACA-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49eeac38-fa8a-45a3-bc27-eb708b86d1c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACA-10A (Blood Derived Normal), aliquot TCGA-DD-AACA-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83a8f01b-aee3-4e47-90a1-9b06cf6c96cc

The open-access MAF lists 150 somatic variants for this specimen: 119 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 27, Nonsense Mutation 9, Splice Region 2, Frame Shift Ins 2, RNA 2, In Frame Del 2, Splice Site 2, 5'UTR 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 134/286 reads (47%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 55/128 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.1523T>G p.I508S | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV99699870; called by muse, mutect2, varscan2
- ADAM28 | c.1772A>C p.E591A | Missense Mutation (SNP) | VAF 87/104 reads (84%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.698); catalogued as COSV99738814; called by muse, mutect2, varscan2
- ADAM30 | c.328T>G p.C110G | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101023886; called by muse, mutect2, varscan2
- ADAMTS12 | c.1973G>T p.C658F | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100711078; called by muse, mutect2, varscan2
- ADCY2 | c.1107A>G p.I369M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603025; called by muse, mutect2, varscan2
- ADGRB2 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 87/97 reads (90%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.276); catalogued as COSV99927083; called by muse, mutect2, varscan2
- APOA1 | c.485A>C p.Q162P | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs780347391, COSV99369293; called by muse, mutect2, varscan2
- C5orf22 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745442454, COSV57599943; called by muse, mutect2, varscan2
- CAMK2A | c.1339G>A p.A447T (on ENST00000348628 / NM_171825.2; = p.A458T on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs748774194, COSV100652046; called by muse, mutect2, varscan2
- CD33 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.151); catalogued as COSV99220847; called by muse, mutect2, varscan2
- CDCP1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 69/142 reads (49%) | catalogued as COSV99944083; called by muse, mutect2, varscan2
- CDH15 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.918); catalogued as rs773943777, COSV57024818; called by muse, mutect2, varscan2
- CDH2 | c.181A>T p.S61C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV99297103; called by muse, varscan2
- CDH7 | c.504G>A p.V168= | Splice Region (SNP) | VAF 43/91 reads (47%) | catalogued as COSV100542526; called by muse, mutect2, varscan2
- CDKN1B | c.275del p.P92Rfs*27 | Frame Shift Del (DEL) | VAF 241/622 reads (39%) | catalogued as COSV57430859; called by mutect2, pindel, varscan2
- CEP120 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336252873, COSV100071533; called by muse, mutect2, varscan2
- CHUK | c.1950A>G p.I650M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV100957293; called by muse, mutect2, varscan2
- CIRBP | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58011635; called by muse, mutect2, varscan2
- CNTNAP2 | c.1088A>T p.N363I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100673571; called by muse, mutect2, varscan2
- COL11A1 | c.3352C>A p.P1118T | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV62192162; called by muse, mutect2, varscan2
- COL4A4 | c.2323C>A p.L775I | Missense Mutation (SNP) | VAF 100/196 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV100307896; called by muse, mutect2, varscan2
- COL5A1 | c.3656G>A p.G1219D | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880039; called by muse, mutect2, varscan2
- CTNNA3 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100373941; called by muse, mutect2, varscan2
- CUBN | c.2620G>A p.V874I | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.024); catalogued as COSV100912805; called by muse, mutect2, varscan2
- DDX6 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 116/395 reads (29%) | catalogued as COSV50588244; called by muse, mutect2, varscan2
- DEFB129 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV55731043, COSV99857470; called by muse, mutect2, varscan2
- DTNBP1 | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs536290179, COSV100161206; called by muse, mutect2, varscan2
- EFR3A | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99603056; called by muse, mutect2, varscan2
- ETAA1 | c.1172C>G p.P391R | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV55475056, COSV99712990; called by muse, varscan2
- EVC2 | c.1949T>G p.F650C | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV100187086; called by muse, mutect2, varscan2
- FEZF2 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV51862718, COSV99334780; called by muse, mutect2, varscan2
- FFAR2 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99876085; called by muse, mutect2, varscan2
- FILIP1L | c.2071G>T p.E691* (on ENST00000354552 / NM_182909.3; = p.E451* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100497427; called by muse, mutect2, varscan2
- FLG | c.4958C>T p.S1653L | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV100911635; called by muse, mutect2, varscan2
- FLI1 | c.451T>A p.L151M | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99858169; called by muse, varscan2
- FNDC1 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.017); catalogued as rs772608315, COSV51939704, COSV51944003; called by muse, mutect2, varscan2
- FOXD4L5 | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101073296; called by muse, mutect2, varscan2
- FRMD4B | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101273475; called by muse, mutect2, varscan2
- FYB2 | c.1701A>G p.L567= | Splice Region (SNP) | VAF 37/96 reads (39%) | catalogued as COSV100599579; called by muse, mutect2, varscan2
- GABRA6 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV50877496; called by muse, mutect2, varscan2
- GCC1 | c.1985G>T p.R662L | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100365703, COSV58462562; called by muse, mutect2, varscan2
- GGT1 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV99958972; called by muse, mutect2, varscan2
- GRID1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as rs762175531, COSV60020849; called by muse, mutect2, varscan2
- GYS1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs933420343, COSV54402838; called by muse, mutect2, varscan2
- HAAO | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99685408; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.227A>T p.D76V (on ENST00000354667 / NM_031243.3; = p.D64V on NM_002137.4) | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100523029; called by muse, varscan2
- HSPA1B | c.188C>G p.P63R | Missense Mutation (SNP) | VAF 118/300 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100989284; called by muse, varscan2
- IGKV1D-17 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs747996565; called by muse, mutect2, varscan2
- INHBE | c.445A>G p.R149G | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99875301; called by muse, mutect2, varscan2
- IZUMO1 | c.826T>C p.S276P | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99710836; called by muse, mutect2, varscan2
- KCND3 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100138082, COSV56185047; called by muse, mutect2, varscan2
- KDM2B | c.2390A>T p.D797V | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100997689; called by muse, mutect2, varscan2
- KIF26B | c.5419C>T p.R1807C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1320589019, COSV100832586; called by muse, mutect2, varscan2
- KIT | c.2126C>A p.S709* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | catalogued as COSV99855508; called by muse, mutect2, varscan2
- KLHL35 | c.1161C>G p.H387Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100888798; called by muse, mutect2, varscan2
- LAMA2 | c.5699T>C p.L1900S | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101370518; called by muse, mutect2, varscan2
- LRRC43 | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100337018; called by muse, mutect2, varscan2
- MED12 | c.3686T>A p.V1229E | Missense Mutation (SNP) | VAF 52/55 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV61335442; called by muse, mutect2, varscan2
- MFF | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); catalogued as COSV100449339; called by muse, mutect2, varscan2
- MNDA | c.1066T>C p.W356R | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100933460; called by muse, mutect2, varscan2
- MRPS30 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV101539289; called by muse, mutect2, varscan2
- MTRF1L | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs774580344, COSV100922462; called by muse, mutect2, varscan2
- MYEOV | c.226T>C p.S76P | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100456659; called by muse, mutect2, varscan2
- MYO18A | c.4936C>T p.R1646W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs200860055; called by muse, mutect2, varscan2
- NARS1 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV99900760; called by muse, mutect2, varscan2
- NDNF | c.179C>G p.T60R | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV101113187; called by muse, mutect2, varscan2
- NLRP7 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as rs752841539, COSV100052791; called by muse, mutect2, varscan2
- NPLOC4 | c.1411T>G p.F471V | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100480951; called by muse, mutect2, varscan2
- NUP133 | c.1115T>A p.L372Q | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99772992; called by muse, mutect2, varscan2
- OBSCN | c.5714T>A p.L1905Q | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781560949, COSV99479413; called by muse, mutect2, varscan2
- OR9A2 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV100628299; called by muse, mutect2, varscan2
- PDE6B | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV55325504, COSV99727675; called by muse, mutect2, varscan2
- PER1 | c.1976C>T p.T659I | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100424602; called by muse, mutect2, varscan2
- PLCL2 | c.2351A>G p.Y784C (on ENST00000615277 / NM_001144382.2; = p.Y658C on NM_015184.5) | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs774032875, COSV101196764; called by muse, mutect2, varscan2
- PLEKHG6 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1565455686, COSV99164301; called by muse, mutect2, varscan2
- PLG | c.523T>A p.Y175N | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV99804744; called by muse, mutect2, varscan2
- PPARD | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1383508351, COSV61100865; called by muse, mutect2, varscan2
- PRPF38A | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as rs764346513, COSV99933471; called by muse, mutect2, varscan2
- PSD3 | c.1830-1G>T p.X610_splice | Splice Site (SNP) | VAF 27/33 reads (82%) | catalogued as COSV99676150; called by muse, mutect2, varscan2
- PXK | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100244491; called by muse, mutect2, varscan2
- PXN | c.1060G>A p.A354T (on ENST00000228307 / NM_001080855.3; = p.A320T on NM_002859.4) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.195); catalogued as rs548031679, COSV99936405; called by muse, mutect2, varscan2
- RAD50 | c.641A>C p.K214T | Missense Mutation (SNP) | VAF 182/410 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99529051; called by muse, mutect2, varscan2
- RANGAP1 | c.619A>G p.I207V | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV100663774; called by muse, mutect2, varscan2
- REPS1 | c.1817A>G p.D606G (on ENST00000450536 / NM_001286611.2; = p.D605G on NM_031922.4) | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.272); catalogued as COSV57809194; called by muse, mutect2, varscan2
- RTF1 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV101047872; called by muse, mutect2, varscan2
- SLC32A1 | c.1486A>G p.I496V | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.487); catalogued as COSV99462317; called by muse, mutect2, varscan2
- SLC5A5 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs754164167, COSV55834552, COSV99715104; called by muse, mutect2, varscan2
- SLCO4C1 | c.1529C>A p.S510* | Nonsense Mutation (SNP) | VAF 46/95 reads (48%) | catalogued as COSV100195965; called by muse, mutect2, varscan2
- SMAD7 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100052924; called by muse, mutect2, varscan2
- SPRR1B | c.59A>C p.Q20P | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs201420448, COSV100198367; called by muse, mutect2, varscan2
- SRC | c.1337C>A p.S446* | Nonsense Mutation (SNP) | VAF 36/71 reads (51%) | catalogued as COSV100658096; called by muse, mutect2, varscan2
- SRL | c.1292T>C p.I431T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs765196291, COSV101281343; called by muse, mutect2, varscan2
- SUPT6H | c.1460A>G p.K487R | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100112857; called by muse, mutect2, varscan2
- TENM1 | c.7730A>T p.K2577M | Missense Mutation (SNP) | VAF 83/90 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100950214; called by muse, mutect2, varscan2
- TEX35 | c.699G>T p.R233S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99275059; called by muse, mutect2, varscan2
- TGFBI | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.99); catalogued as rs890309873, COSV100526523; called by muse, mutect2, varscan2
- TMBIM6 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99920722; called by muse, mutect2, varscan2
- TRIOBP | c.2128T>G p.S710A | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV100730892, COSV60376256; called by muse, mutect2, varscan2
- TTLL3 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 172/398 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100047583; called by muse, mutect2, varscan2
- TYRO3 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777686; called by muse, mutect2, varscan2
- USP45 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569728; called by muse, mutect2, varscan2
- USP7 | c.2579C>T p.T860I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as COSV100784204; called by muse, mutect2, varscan2
- VCAN | c.9163G>C p.V3055L | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99425711, COSV99427560; called by muse, mutect2, varscan2
- VCP | c.71A>C p.N24T | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV100734226; called by muse, mutect2, varscan2
- VPS13C | c.1290+2T>C p.X430_splice (on ENST00000644861 / NM_020821.3; = p.X387_splice on NM_017684.5) | Splice Site (SNP) | VAF 33/67 reads (49%) | catalogued as COSV99830504; called by muse, mutect2, varscan2
- VPS52 | c.1701C>G p.N567K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101460437; called by muse, mutect2, varscan2
- WDR11 | c.3250C>G p.Q1084E | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99677048; called by muse, mutect2, varscan2
- ZFHX4 | c.7919G>T p.R2640L | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV99263453; called by muse, mutect2, varscan2
- ZFYVE21 | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 25/27 reads (93%) | catalogued as COSV99162986; called by muse, mutect2, varscan2
- ZNF100 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV99974400; called by muse, mutect2, varscan2
- ZNF512 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.202); catalogued as COSV100820816; called by muse, mutect2, varscan2
- FCGBP | c.8920T>A p.S2974T | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IGKV1-17 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- LGALS7B | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by mutect2, varscan2
- LPCAT1 | c.847_849del p.E283del | In Frame Del (DEL) | VAF 20/54 reads (37%) | called by pindel, varscan2
- PHTF1 | c.1361dup p.M454Ifs*46 | Frame Shift Ins (INS) | VAF 155/376 reads (41%) | called by mutect2, pindel, varscan2
- REEP6 | c.149_172del p.F50_L57del | In Frame Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, varscan2
- ADAMTS9 | c.4122G>A p.E1374= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as rs1450580267, COSV99899564; called by muse, mutect2, varscan2
- ANOS1 | c.798G>A p.V266= | Silent (SNP) | VAF 42/43 reads (98%) | catalogued as COSV99390947; called by muse, mutect2, varscan2
- AOAH | c.21C>A p.I7= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as COSV99333986; called by muse, mutect2, varscan2
- BMS1 | c.1668C>T p.C556= | Silent (SNP) | VAF 61/124 reads (49%) | catalogued as COSV100996722; called by muse, mutect2, varscan2
- CBLN2 | c.600C>G p.L200= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV99504443; called by muse, mutect2, varscan2
- CDRT4 | c.84C>T p.P28= | Silent (SNP) | VAF 30/34 reads (88%) | catalogued as COSV100381620; called by muse, mutect2, varscan2
- COL22A1 | c.708C>A p.T236= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100278774; called by muse, mutect2, varscan2
- DNAH9 | c.11358C>A p.T3786= | Silent (SNP) | VAF 36/38 reads (95%) | catalogued as COSV52346398, COSV99306150; called by muse, mutect2, varscan2
- EPHA8 | c.1716G>A p.K572= | Silent (SNP) | VAF 117/132 reads (89%) | catalogued as COSV51305281; called by muse, mutect2, varscan2
- HEPH | c.684C>T p.L228= (on ENST00000343002; = p.L282= on NM_138737.5) | Silent (SNP) | VAF 120/130 reads (92%) | catalogued as COSV57959803; called by muse, mutect2, varscan2
- KCNA3 | c.1134G>A p.S378= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs764449826, COSV63902769; called by muse, mutect2, varscan2
- KIAA0586 | c.3642A>G p.T1214= (on ENST00000619416 / NM_001244190.2; = p.T1153= on NM_014749.5) | Silent (SNP) | VAF 59/71 reads (83%) | catalogued as rs773464253, COSV99708243; called by muse, mutect2, varscan2
- NAT9 | c.594T>G p.P198= | Silent (SNP) | VAF 68/88 reads (77%) | catalogued as COSV99380080; called by muse, mutect2, varscan2
- NIPA1 | c.354C>A p.L118= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100507938, COSV100508070; called by muse, mutect2, varscan2
- PCDHA1 | c.2232G>C p.A744= | Silent (SNP) | VAF 64/164 reads (39%) | catalogued as COSV100974376, COSV100974390; called by muse, mutect2
- PCDHB12 | c.1881C>A p.A627= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99507947; called by muse, mutect2, varscan2
- PDIA2 | c.1329T>C p.I443= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs1198973166, COSV99249889; called by muse, mutect2, varscan2
- PDXDC1 | c.13C>T p.L5= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs1174672723, COSV100363213; called by muse, mutect2, varscan2
- PLXNA4 | c.3690G>A p.P1230= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs762844713, COSV100327681; called by muse, mutect2, varscan2
- RAB4A | c.216A>G p.Q72= | Silent (SNP) | VAF 128/294 reads (44%) | catalogued as COSV100797095; called by muse, mutect2, varscan2
- REV3L | c.7941A>G p.K2647= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV100725262; called by muse, mutect2, varscan2
- RNF145 | c.1644G>T p.V548= (on ENST00000424310 / NM_001199383.2; = p.V576= on NM_144726.2) | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99193568; called by muse, mutect2, varscan2
- SIGLEC6 | c.477C>T p.G159= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100585441; called by muse, mutect2, varscan2
- SLCO5A1 | c.192G>T p.V64= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV99480173; called by muse, mutect2, varscan2
- STXBP5 | c.2748G>A p.V916= (on ENST00000321680 / NM_001127715.2; = p.V880= on NM_139244.4) | Silent (SNP) | VAF 91/190 reads (48%) | catalogued as COSV99470419; called by muse, mutect2, varscan2
- TST | c.660T>C p.D220= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV99968203; called by muse, mutect2, varscan2
- ZBTB41 | c.1410A>G p.K470= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs1159840025, COSV100963164; called by muse, mutect2, varscan2
- DCHS2 | n.5954C>A | RNA (SNP) | VAF 83/192 reads (43%) | catalogued as COSV61780163; called by muse, mutect2, varscan2
- DCHS2 | n.5953T>C | RNA (SNP) | VAF 82/191 reads (43%) | catalogued as COSV100602781; called by muse, mutect2, varscan2
- INPPL1 | c.*2A>G | 3'UTR (SNP) | VAF 58/141 reads (41%) | catalogued as COSV99996301; called by muse, mutect2, varscan2
- VPS50 | c.-2A>T | 5'UTR (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99298215; called by muse, mutect2, varscan2
